Somatic mutation profile of tumor specimen TCGA-AC-A6IX-01A (aliquot TCGA-AC-A6IX-01A-12D-A32I-09) from TCGA case TCGA-AC-A6IX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 49.2 years (17,969 days).
Specimen TCGA-AC-A6IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb448c02-5c0d-4257-aa09-31528655980c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A6IX-10A (Blood Derived Normal), aliquot TCGA-AC-A6IX-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdb6710c-3184-4119-859f-6c255837ca42

The open-access MAF lists 51 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Frame Shift Del 3, 5'Flank 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRH | c.672A>T p.Q224H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV100813289; called by muse, mutect2, varscan2
- AIFM1 | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV99780879; called by muse, mutect2, varscan2
- AL136295.1 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99937884; called by muse, mutect2, varscan2
- ALMS1 | c.11134G>C p.E3712Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100041737; called by muse, mutect2, varscan2
- AMER3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200636300, COSV100366224, COSV58467211; called by muse, mutect2, varscan2
- ANKAR | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV55612787; called by muse, mutect2, varscan2
- ASB7 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.322); catalogued as COSV100235083; called by muse, mutect2, varscan2
- CLIP1 | c.3766G>A p.V1256I (on ENST00000620786 / NM_001247997.1; = p.V1245I on NM_002956.2) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.037); catalogued as COSV100211428; called by muse, mutect2, varscan2
- COL6A6 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650055; called by muse, mutect2, varscan2
- CPT1C | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1477576811, COSV54920207, COSV99773483; called by muse, mutect2, varscan2
- FAM47C | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV63727158, COSV63731239; called by muse, mutect2, varscan2
- FBXO25 | c.1028C>G p.P343R (on ENST00000382824 / NM_183421.2; = p.P267R on NM_012173.3) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366815; called by muse, mutect2, varscan2
- ITGB2 | c.1831C>T p.R611C (on ENST00000302347; = p.R587C on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as rs202025124; called by muse, mutect2, varscan2
- LPAR6 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1422919265, COSV99923844; called by muse, mutect2, varscan2
- MCRS1 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100657327; called by muse, mutect2, varscan2
- MEA1 | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99775638, COSV99775826; called by muse, mutect2, varscan2
- MED15 | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.799); catalogued as COSV99487493; called by muse, mutect2, varscan2
- MEN1 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM021294, COSV99580601; called by muse, mutect2, varscan2
- MMP19 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as COSV100491016; called by muse, mutect2, varscan2
- MUC6 | c.6445C>T p.H2149Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as COSV101424467; called by muse, mutect2, varscan2
- MYOM2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs144235879; called by muse, mutect2, varscan2
- NCOA7 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs767033570, COSV99996715; called by muse, mutect2, varscan2
- OR51G1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58968273; called by muse, mutect2, varscan2
- PAN2 | c.2635C>T p.H879Y (on ENST00000425394 / NM_001127460.3; = p.H875Y on NM_014871.5) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV99228181; called by muse, mutect2, varscan2
- PRKD1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119611; called by muse, mutect2, varscan2
- RLF | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV65652396; called by muse, mutect2, varscan2
- SLC9A8 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760094888, COSV64291897; called by muse, mutect2, varscan2
- STAG3 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs539912996, COSV57933950; called by muse, mutect2, varscan2
- TRHR | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.19); catalogued as COSV100304757; called by muse, mutect2, varscan2
- TRMT2B | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100105263; called by muse, mutect2, varscan2
- TXNDC5 | c.1204T>C p.F402L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99306586; called by muse, mutect2, varscan2
- VPS13C | c.4199C>T p.S1400L (on ENST00000644861 / NM_020821.3; = p.S1357L on NM_017684.5) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99827787; called by muse, mutect2, varscan2
- WHAMM | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99724749; called by muse, mutect2
- ZFYVE26 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as rs979216812, COSV100720231; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1366_1367del p.P456Cfs*32 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- CDH1 | c.1709del p.N570Mfs*14 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.923_924del p.V308Gfs*20 | Frame Shift Del (DEL) | VAF 28/199 reads (14%) | called by pindel, varscan2
- ZNF394 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.127); called by muse, mutect2
- ALG1 | c.1246C>T p.L416= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as rs1471589709, COSV99275551; called by muse, mutect2, varscan2
- BCAR3 | c.102C>G p.L34= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV53077307, COSV99550482; called by muse, mutect2, varscan2
- GPR61 | c.729G>A p.G243= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100879848; called by muse, mutect2, varscan2
- KCNB2 | c.1581G>A p.T527= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs909418624, COSV73050592; called by muse, mutect2, varscan2
- KIF26B | c.2550C>T p.S850= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs765221697, COSV100831884; called by muse, mutect2, varscan2
- PCDHA2 | c.144C>T p.I48= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100973709, COSV65365365; called by muse, mutect2, varscan2
- PROS1 | c.177C>T p.I59= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs764115962, COSV100820223; called by muse, mutect2, varscan2
- SLC27A1 | c.1314C>T p.L438= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99393118; called by muse, mutect2, varscan2
- TBCC | c.288A>G p.K96= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as COSV99773942; called by muse, mutect2, varscan2
- TRAV12-2 | c.327C>T p.L109= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502547 T>C | 5'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847792 G>A | 5'Flank (SNP) | VAF 57/250 reads (23%) | called by muse, mutect2, varscan2
